Somatic mutation profile of tumor specimen TCGA-2G-AAGX-01A (aliquot TCGA-2G-AAGX-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGX, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, benign; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 22.8 years (8,326 days).
Specimen TCGA-2G-AAGX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3873b455-84a8-4e4b-b015-f3ae788d4971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGX-10A (Blood Derived Normal), aliquot TCGA-2G-AAGX-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/558b509c-5291-4268-94d3-6a8015748852

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, In Frame Del 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSNK2A1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 99/223 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs1236777749, COSV99424528; called by muse, mutect2, varscan2
- SORBS3 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs778240076; called by muse, mutect2, varscan2
- ZNF189 | c.1865C>G p.T622R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV52275892; called by muse, mutect2, varscan2
- ACIN1 | c.3368C>A p.P1123H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADSS2 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AUNIP | c.545_547del p.S182del | In Frame Del (DEL) | VAF 43/174 reads (25%) | called by mutect2, pindel, varscan2
- GRIK3 | c.800T>C p.L267S | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- CDRT15 | c.436A>C p.R146= | Silent (SNP) | VAF 60/376 reads (16%) | called by muse, mutect2, varscan2
- TCF3 | c.1587-57G>A | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as rs780136754; called by muse, mutect2, varscan2
